Somatic mutation profile of tumor specimen C3N-02423-01 (aliquot CPT0146980010) from CPTAC case C3N-02423, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 70.3 years (25,686 days).
Specimen C3N-02423-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec4016ee-43a3-4f19-b727-46ac2a1248d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02423-71 (Blood Derived Normal), aliquot CPT0147010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a07910aa-cc07-41cf-b8b9-40e5f46446a5

The open-access MAF lists 623 somatic variants for this specimen: 422 protein-altering or splice-affecting, 122 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 122, Nonsense Mutation 40, Intron 33, 5'UTR 15, Splice Site 12, RNA 11, 3'UTR 10, 3'Flank 8, Frame Shift Del 6, Splice Region 5, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 54/280 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 48/265 reads (18%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99574270; called by muse, mutect2
- ADGRF5 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.035); catalogued as COSV51930877; called by muse, mutect2
- AGL | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs1168287000; called by muse, mutect2
- ANKLE1 | c.376C>T p.R126* (on ENST00000394458; = p.R72* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as rs1254636473; called by muse, mutect2
- APLP1 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as COSV55707127; called by muse, mutect2, varscan2
- APOB | c.5191del p.V1731Sfs*12 | Frame Shift Del (DEL) | VAF 36/264 reads (14%) | catalogued as COSV99263135; called by mutect2, pindel, varscan2
- ARHGAP10 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV60598630; called by muse, mutect2
- ARHGEF10 | c.1273A>G p.I425V (on ENST00000398564; = p.I400V on NM_014629.4) | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1181158832; called by muse, varscan2
- ASL | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 99/605 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs933291133; called by muse, mutect2, varscan2
- ATCAY | c.647+1G>C p.X216_splice | Splice Site (SNP) | VAF 51/192 reads (27%) | catalogued as rs372569029; called by muse, mutect2, varscan2
- ATM | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1565344141; ClinVar: uncertain significance; called by muse, mutect2
- ATP8A2 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54958704; called by muse, mutect2
- BARHL1 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1336508111; called by muse, mutect2, varscan2
- BIRC6 | c.1166C>A p.S389Y | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV101428347; called by muse, mutect2
- BIRC6 | c.1319C>G p.S440* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | catalogued as COSV70204005; called by muse, mutect2
- BMP7 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 173/604 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV67782455; called by muse, mutect2, varscan2
- C1orf226 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1367908683; called by muse, mutect2
- C2CD2 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs1471813784; called by muse, mutect2, varscan2
- CACNG5 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1010497856; called by muse, mutect2, varscan2
- CACTIN | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs755272837; called by muse, mutect2
- CCDC124 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as rs1264663107; called by muse, mutect2
- CEP135 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.526); catalogued as COSV57261125; called by muse, mutect2, varscan2
- CHD7 | c.2690G>T p.R897L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as CM158518; called by muse, mutect2, varscan2
- CLEC4F | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV99713700; called by muse, mutect2, varscan2
- CNTN4 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs377113483, COSV68561748; called by muse, mutect2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 29/401 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2
- COASY | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.101); catalogued as rs759581809; called by muse, mutect2, varscan2
- CTC1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs753275597, COSV100236227; called by muse, mutect2, varscan2
- CTNND2 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as CM152500; called by muse, mutect2, varscan2
- DLC1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs1217234965, COSV52292955; called by muse, mutect2
- DMTF1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV58685274; called by muse, mutect2
- DNAH14 | c.6252G>C p.L2084F (on ENST00000445597; = p.L2737F on NM_001367479.1) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369507297; called by muse, mutect2
- DNAH6 | c.11964C>G p.I3988M | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV99408335; called by muse, mutect2
- DNAH7 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56780713; called by muse, mutect2, varscan2
- DNHD1 | c.7664G>A p.R2555Q | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs1334288367; called by muse, mutect2, varscan2
- DNMBP | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.365); catalogued as COSV60622709; called by muse, mutect2
- DTX3L | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV56143972; called by muse, mutect2
- EP300 | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 24/446 reads (5%) | catalogued as COSV54344228; called by muse, mutect2
- EPG5 | c.2907G>A p.W969* | Nonsense Mutation (SNP) | VAF 68/362 reads (19%) | catalogued as COSV56346455; called by muse, mutect2, varscan2
- FAT1 | c.7349C>G p.S2450* | Nonsense Mutation (SNP) | VAF 12/208 reads (6%) | catalogued as COSV71673814, COSV71675311; called by muse, mutect2
- FFAR3 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 16/358 reads (4%) | catalogued as COSV59909552; called by muse, mutect2
- FITM1 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs369273538; called by muse, mutect2
- FLG | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 18/545 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as COSV100910459; called by muse, mutect2
- FLVCR1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1476675229, COSV65324173; called by muse, mutect2
- FOXB2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65023273; called by muse, mutect2
- FRRS1L | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as COSV73747004; called by muse, mutect2
- FUT5 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs561364366, COSV53136516; called by muse, mutect2
- FZD3 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.669); catalogued as COSV53534291; called by muse, mutect2, varscan2
- GAP43 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs11557765, COSV100526061; called by muse, mutect2
- GPATCH2 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861874, COSV65132637; called by muse, mutect2
- GREB1L | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1329384362; called by muse, mutect2, varscan2
- GRHPR | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 17/576 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1383439544, COSV58942464; called by muse, mutect2
- GRIK2 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100029182; called by muse, mutect2, varscan2
- GUCY1A1 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs771725701; called by muse, mutect2
- HDAC2 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1554198179; ClinVar: uncertain significance; called by muse, mutect2
- HERC2 | c.11312G>C p.R3771T | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55339137; called by muse, mutect2, varscan2
- HIVEP2 | c.3303G>C p.Q1101H | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as rs1424706959, COSV50026078; called by muse, mutect2
- HNRNPCL2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as rs752588101, COSV60404498; called by muse, mutect2, varscan2
- HRNR | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV64254333, COSV64260136; called by muse, mutect2
- HSPG2 | c.10327G>T p.G3443C | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65933290; called by muse, mutect2
- ICE1 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV56826899; called by muse, mutect2
- IFT46 | c.815C>T p.S272L (on ENST00000264021 / NM_001168618.2; = p.S323L on NM_020153.3) | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as rs45508996; called by muse, mutect2
- IQSEC2 | c.1102G>C p.E368Q (on ENST00000642864 / NM_001111125.3; = p.E163Q on NM_015075.2) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs1556864716; called by muse, mutect2
- JMY | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as rs772331132, COSV99061466; called by muse, mutect2
- KCNK13 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99965899, COSV99965985; called by muse, mutect2
- KIR3DL3 | c.1055-1G>T p.X352_splice | Splice Site (SNP) | VAF 56/348 reads (16%) | catalogued as rs770908274, COSV99399674; called by mutect2, varscan2
- KLC3 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1469502761; called by muse, mutect2
- LATS1 | c.2845C>G p.P949A | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53589046; called by muse, mutect2
- LRRC72 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs959797850; called by muse, mutect2, varscan2
- LRRTM4 | c.1594C>A p.Q532K | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.9); catalogued as COSV69166613; called by muse, mutect2
- LSM8 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 27/225 reads (12%) | catalogued as rs771084186, COSV50800522; called by muse, mutect2, varscan2
- LTBP1 | c.4624G>T p.G1542C (on ENST00000404816 / NM_206943.4; = p.G1216C on NM_000627.4) | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55376866, COSV55382584, COSV55382653; called by muse, mutect2, varscan2
- MAP4K1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV101204229; called by muse, mutect2, varscan2
- MORN1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs963639641; called by muse, mutect2, varscan2
- MUC16 | c.35599C>G p.L11867V | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.047); catalogued as rs1292506143, COSV67470654; called by muse, mutect2
- MUC16 | c.34166C>T p.S11389L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV67500193; called by muse, mutect2
- MUC16 | c.32369C>T p.S10790L | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.351); catalogued as COSV101197798, COSV67480339; called by muse, mutect2
- MUC16 | c.31894C>T p.H10632Y | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.332); catalogued as rs1035245741; called by muse, mutect2
- MYBPC3 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 10/135 reads (7%) | catalogued as COSV99920854; called by muse, mutect2
- NAV2 | c.2807A>T p.N936I (on ENST00000396087 / NM_001244963.2; = p.N913I on NM_145117.5) | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs367996273; called by muse, mutect2, varscan2
- NKAPL | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561868233, COSV59198625; called by muse, mutect2
- NLGN4X | c.2101G>T p.D701Y | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52026313, COSV99322183; called by muse, mutect2, varscan2
- NLRP11 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV100789656; called by muse, mutect2
- NRXN1 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV101277085; called by muse, mutect2, varscan2
- NSMCE4A | c.989-1G>C p.X330_splice | Splice Site (SNP) | VAF 8/114 reads (7%) | catalogued as COSV64632687; called by muse, mutect2
- ODF2 | c.378G>C p.K126N (on ENST00000434106 / NM_153433.2; = p.K102N on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100654379; called by muse, mutect2
- OR13C5 | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66164199; called by muse, mutect2, varscan2
- OR2M2 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs147832484, COSV100677137; called by muse, mutect2
- OR4C15 | c.433A>T p.I145F (on ENST00000314644; = p.I91F on NM_001001920.2) | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58952216; called by muse, mutect2, varscan2
- OTOG | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs749040674, COSV61131569; called by muse, mutect2, varscan2
- OTUD4 | c.414+1G>T p.X138_splice (on ENST00000447906 / NM_001366057.1; = p.X73_splice on NM_017493.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/158 reads (14%) | catalogued as rs750883697; called by muse, mutect2, varscan2
- PDK3 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1356075616, COSV64792730; called by muse, mutect2, varscan2
- PGLYRP4 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV100668378; called by muse, mutect2
- PIKFYVE | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100011605, COSV100011627; called by muse, mutect2
- PKD1L2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 14/366 reads (4%) | catalogued as rs1046009612, COSV61412147; called by muse, mutect2
- PLCB4 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148851937, COSV53797028; called by muse, varscan2
- PLRG1 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57424443; called by muse, mutect2
- PLXNA4 | c.2831G>T p.R944L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100323287, COSV100323591; called by muse, mutect2, varscan2
- POLM | c.1089C>G p.H363Q | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1268552848; called by muse, mutect2, varscan2
- PRDM9 | c.1376G>T p.R459M | Missense Mutation (SNP) | VAF 63/494 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV99691117; called by muse, mutect2, varscan2
- PTPN3 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs539799147, COSV52701835; called by muse, mutect2
- PTPRH | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs746623909; called by muse, mutect2, varscan2
- PTPRQ | c.1118T>C p.I373T (on ENST00000616559; = p.I331T on NM_001145026.2) | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1244386570; called by muse, mutect2, varscan2
- RECQL4 | c.3454G>C p.E1152Q | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV56741932, COSV56742746; called by muse, mutect2
- REPS2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs949060639, COSV58188090; called by muse, mutect2, varscan2
- RESF1 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57019810; called by muse, mutect2
- RIF1 | c.3643A>G p.T1215A | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs371962016; called by muse, mutect2, varscan2
- RNASEH1 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV59438377; called by muse, mutect2
- RNF213 | c.5743C>G p.L1915V | Missense Mutation (SNP) | VAF 23/625 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60408175; called by muse, mutect2
- ROS1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.362); catalogued as COSV63862083; called by muse, mutect2
- RUNDC1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100799374; called by muse, mutect2
- SAMD15 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs1208697141; called by muse, mutect2
- SARDH | c.1008C>G p.I336M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV64096980, COSV64097705; called by muse, mutect2
- SCAF4 | c.3092G>A p.R1031K | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV54256261; called by muse, mutect2
- SH3PXD2B | c.288A>G p.I96M | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as COSV61130802; called by muse, mutect2, varscan2
- SKIDA1 | c.2533C>T p.H845Y | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV101481266, COSV71610417; called by muse, mutect2, varscan2
- SMAD4 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV61685296, COSV61696805; called by muse, mutect2
- SOS1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs771878514, COSV67675040; called by muse, mutect2
- SPRED3 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1358171883; called by muse, mutect2, varscan2
- SQSTM1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as rs867275286; ClinVar: uncertain significance; called by muse, mutect2
- SVEP1 | c.7021G>A p.E2341K | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.385); catalogued as COSV99929643; called by muse, mutect2
- TAF1L | c.3898C>T p.L1300F | Missense Mutation (SNP) | VAF 181/596 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54258772; called by muse, mutect2, varscan2
- TF | c.1988G>C p.R663T | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV53921793; called by muse, mutect2
- TMEM238 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV59805053; called by muse, mutect2
- TOX4 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV52971422; called by muse, mutect2
- TRIB1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as rs1457004284; called by muse, mutect2
- TRMT10A | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1445422188; called by muse, mutect2
- TTC30A | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63101719; called by muse, mutect2
- TTN | c.14155G>A p.E4719K (on ENST00000591111; = p.E3792K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/235 reads (4%) | PolyPhen benign (0.121); catalogued as rs1353528713; called by muse, mutect2
- TUB | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs745541617; called by muse, mutect2, varscan2
- TXK | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746410519, COSV51912925; called by muse, mutect2, varscan2
- ULK4 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as rs1179805363; called by muse, mutect2
- USH2A | c.10163C>T p.S3388L | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV56433498; called by muse, mutect2
- USP32 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100341096, COSV56267657, COSV56279028; called by muse, mutect2
- USP36 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); catalogued as COSV61750280; called by muse, mutect2
- VCAN | c.4849G>C p.E1617Q | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99426231; called by muse, varscan2
- VEGFC | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768314100; called by muse, mutect2, varscan2
- XIRP2 | c.3232G>C p.E1078Q (on ENST00000628543; = p.E1253Q on NM_152381.6) | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV54710516; called by muse, mutect2
- YEATS4 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56088031; called by muse, mutect2
- ZBTB49 | c.1773G>C p.E591D | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100552371, COSV100552656; called by muse, mutect2
- ZNF148 | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV62305412; called by muse, mutect2
- ZNF256 | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56599889; called by muse, mutect2
- ZNF469 | c.8458G>A p.D2820N (on ENST00000437464; = p.D2848N on NM_001367624.2) | Missense Mutation (SNP) | VAF 46/538 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV101459000; called by muse, mutect2
- ZNF784 | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 14/237 reads (6%) | catalogued as COSV100323274; called by muse, mutect2
- ZNF814 | c.1861C>G p.H621D | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs774286359; called by muse, mutect2
- ACADSB | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL4 | c.288del p.D97Tfs*12 | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | called by mutect2, pindel, varscan2
- AEBP1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- AFTPH | c.185C>G p.S62* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- AMER3 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); called by muse, mutect2
- ANKRD33B | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- APBA2 | c.1064T>A p.V355E | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- APC | c.7226G>C p.G2409A | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.136); called by muse, mutect2
- ARHGAP32 | c.4492C>T p.P1498S (on ENST00000310343 / NM_001378025.1; = p.P1149S on NM_014715.4) | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGEF28 | c.2201C>T p.S734F | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- ARSD | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ATG4D | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2
- ATG7 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- ATP8A1 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- AXIN1 | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2
- BANK1 | c.257C>G p.S86* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- BORA | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.06); called by muse, mutect2
- C15orf39 | c.2860C>T p.Q954* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- C17orf50 | c.173A>C p.E58A | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- C1orf174 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- C3orf14 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- C5orf52 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAD | c.4321G>A p.G1441S | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CADM1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2
- CAPZA1 | c.586-7C>G | Splice Region (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- CARMIL2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2
- CCDC146 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 23/368 reads (6%) | called by muse, mutect2
- CCNK | c.616A>T p.I206L | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CD207 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CD44 | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CDC37 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDK13 | c.4282G>C p.E1428Q | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- CEP295 | c.5035G>T p.A1679S | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CEP350 | c.3713G>A p.G1238E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERCAM | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CIAO3 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CIBAR1 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CNTN3 | c.1880C>A p.P627Q | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A3 | c.1455del p.L486Sfs*16 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- COL6A2 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CORO2A | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CPVL | c.462+1G>C p.X154_splice | Splice Site (SNP) | VAF 40/257 reads (16%) | called by muse, mutect2, varscan2
- CRAMP1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRHR2 | c.1206C>A p.F402L | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD1 | c.5518G>T p.G1840* (on ENST00000520002; = p.G1839* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.5986T>C p.Y1996H (on ENST00000297405 / NM_001363185.1; = p.Y1892H on NM_052900.3) | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CTIF | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 42/453 reads (9%) | called by muse, mutect2
- CTTNBP2NL | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- CTXN2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 47/302 reads (16%) | called by muse, mutect2, varscan2
- CWC25 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- DACT2 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.496); called by muse, mutect2
- DBH | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 39/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX58 | c.1008G>C p.Q336H | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- DDX60L | c.3915G>T p.Q1305H | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DEF6 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DHX36 | c.369-1G>T p.X123_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- DLGAP4 | c.2513-1G>T p.X838_splice (on ENST00000339266 / NM_001365621.1; = p.X835_splice on NM_014902.6) | Splice Site (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- DNAJB5 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 36/850 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); called by muse, mutect2
- DSG3 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DUSP11 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- EEF1A1 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- EEFSEC | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 35/381 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EHMT1 | c.1643A>T p.H548L | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2
- ELK4 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.236); called by muse, mutect2
- ENO4 | c.1589C>T p.S530L (on ENST00000622726; = p.S527L on NM_001242699.2) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ERCC4 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2
- EXD2 | c.472G>C p.D158H (on ENST00000312994 / NM_001193362.1; = p.D33H on NM_018199.3) | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- EXT1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171B | c.924G>T p.M308I | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM234A | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FASN | c.7456G>C p.E2486Q | Missense Mutation (SNP) | VAF 37/602 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT1 | c.7480C>T p.Q2494* | Nonsense Mutation (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- FAT1 | c.6511C>A p.P2171T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAT4 | c.12475G>C p.D4159H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXW10 | c.2335+2T>A p.X779_splice | Splice Site (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- FIZ1 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2
- FLG2 | c.6697G>A p.A2233T | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); called by muse, mutect2
- FNIP2 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- FOLH1 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FTH1 | c.341C>A p.S114* | Nonsense Mutation (SNP) | VAF 32/638 reads (5%) | called by muse, mutect2
- GABRD | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 29/420 reads (7%) | called by muse, mutect2
- GCC2 | c.3415C>T p.Q1139* | Nonsense Mutation (SNP) | VAF 11/296 reads (4%) | called by muse, mutect2
- GLRA1 | c.1352G>C p.R451T (on ENST00000455880 / NM_001146040.2; = p.R443T on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); called by muse, mutect2
- GOLGA6L7 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GOLGA8K | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 40/1102 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- GPC6 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GRID2 | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 63/455 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- GRIK3 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSPT1 | c.1389C>G p.I463M (on ENST00000420576 / NM_001130007.2; = p.I601M on NM_002094.4) | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2
- HDGFL3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- HEATR4 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HECW1 | c.4067A>G p.Y1356C | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.292); called by muse, mutect2
- HELZ2 | c.2171A>G p.Y724C (on ENST00000467148 / NM_001037335.2; = p.Y155C on NM_033405.3) | Missense Mutation (SNP) | VAF 94/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HHLA2 | c.912G>C p.L304F | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HINFP | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIVEP3 | c.6256C>A p.P2086T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HOXD4 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HPS3 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.58); called by muse, mutect2
- HRNR | c.1117A>G p.S373G | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- HSP90B1 | c.1309-4G>A | Splice Region (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2
- HTR1B | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- IBTK | c.2688A>C p.L896F | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.086); called by muse, mutect2
- IFT57 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2
- IGSF10 | c.1493C>A p.P498Q | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- IL15 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- IL17RA | c.1308_1327del p.M436Ifs*68 | Frame Shift Del (DEL) | VAF 34/458 reads (7%) | called by mutect2, pindel
- IL1RL1 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRX5 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAX | c.2989C>G p.R997G | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITGB8 | c.1057-2A>G p.X353_splice | Splice Site (SNP) | VAF 22/146 reads (15%) | called by mutect2, varscan2
- ITLN2 | c.488A>C p.H163P | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KALRN | c.8159A>G p.K2720R (on ENST00000360013 / NM_001024660.4; = p.K1023R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KANK2 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 12/321 reads (4%) | called by muse, mutect2
- KATNIP | c.4687C>T p.H1563Y | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAZALD1 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.042); called by muse, mutect2
- KIAA1109 | c.5326G>C p.E1776Q | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.146); called by muse, mutect2
- KIAA1210 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- KIF9 | c.471del p.Y158Mfs*9 | Frame Shift Del (DEL) | VAF 38/450 reads (8%) | called by mutect2, pindel
- KLHDC9 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KLHL38 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KMT2D | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- KPRP | c.885C>A p.C295* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- KRTAP23-1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2
- LCE2B | c.71G>C p.C24S | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- LIG3 | c.2331G>T p.K777N | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- LMAN1L | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2
- LMBR1L | c.1149A>T p.R383S | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRP2 | c.10567G>C p.E3523Q | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAD2L2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MAP1A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- MAP2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); called by muse, mutect2
- MAX | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2
- MCCC1 | c.542dup p.Y181* | Nonsense Mutation (INS) | VAF 64/462 reads (14%) | called by mutect2, pindel, varscan2
- MDGA2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2
- MDM4 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED1 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- METTL11B | c.831del p.H278Tfs*52 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- MGAM2 | c.5123A>G p.D1708G | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAT5B | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MMEL1 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- MMP26 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP26 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MUC22 | c.3162G>T p.M1054I | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0.02); called by muse, mutect2
- MYBPC1 | c.2407G>C p.D803H (on ENST00000550270 / NM_206820.2; = p.D810H on NM_002465.4) | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- MYH3 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYLK | c.2019G>C p.Q673H | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NEDD1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NEK3 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- NEO1 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- NETO2 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- NFRKB | c.3566C>G p.S1189C (on ENST00000446488 / NM_001143835.2; = p.S1214C on NM_006165.3) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NLGN4X | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NLGN4X | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRC5 | c.2140G>T p.G714W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- NME9 | c.992G>C p.*331Sext*28 | Nonstop Mutation (SNP) | VAF 15/246 reads (6%) | called by muse, mutect2
- NOL7 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); called by muse, mutect2
- NOL9 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- NRXN3 | c.3249C>A p.N1083K (on ENST00000335750 / NM_001330195.2; = p.N710K on NM_004796.6) | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NUMBL | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR11H6 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- OR2B3 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- OR4A5 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR4N2 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OR4Q3 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6F1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR6K3 | c.883G>T p.V295L (on ENST00000368146; = p.V279L on NM_001005327.2) | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- OR8K5 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OSMR | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); called by muse, mutect2
- PCDHGA4 | c.2318G>T p.G773V | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNX1 | c.5896G>C p.E1966Q | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDXDC1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- PDZRN3 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- PKD1L1 | c.7315G>A p.E2439K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PKP1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PKP1 | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLCB3 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.22); called by muse, mutect2
- PLD1 | c.2149C>G p.P717A | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- PLEKHG2 | c.3934C>A p.P1312T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLPP5 | c.74+5G>A | Splice Region (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- POLR2A | c.2470G>C p.E824Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPM1D | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
- PRDM8 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 53/345 reads (15%) | called by muse, mutect2, varscan2
- PRMT1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PROM2 | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PRUNE2 | c.2048C>A p.P683H | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSENEN | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 29/471 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PSKH2 | c.7T>C p.C3R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- PTPRO | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2
- PXDN | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2
- PXDNL | c.3177A>T p.L1059F | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RANGRF | c.352-5C>T | Splice Region (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- RBBP8NL | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF113B | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2
- RNF4 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.115); called by muse, mutect2
- RPL34 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- RPS6KA5 | c.1873C>G p.H625D | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- RUSF1 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 25/411 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.244); called by muse, mutect2
- RYR2 | c.1588C>G p.L530V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR2 | c.2182G>C p.D728H | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR2 | c.6129A>T p.Q2043H | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- S1PR3 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.991); called by muse, mutect2
- SACS | c.12116A>G p.K4039R | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SCN1A | c.2252C>T p.S751F (on ENST00000303395 / NM_001202435.3; = p.S740F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2
- SCN3A | c.4384C>G p.L1462V | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEPTIN9 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 39/569 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2
- SFSWAP | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SGO1 | c.1636T>C p.F546L (on ENST00000263753 / NM_001012410.5; = p.F277L on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/190 reads (18%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SHISAL2A | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SIGIRR | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); called by muse, mutect2
- SLC39A3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC41A3 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SLC45A1 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLX4 | c.5074G>C p.D1692H | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2
- SMG1 | c.2809C>G p.Q937E | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- SMR3A | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- SP100 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); called by muse, mutect2
- SPAG4 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- SPRTN | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2
- SRRM2 | c.1380G>T p.K460N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SSX2 | c.467-1G>T p.X156_splice (on ENST00000337502 / NM_175698.2; = p.X205_splice on NM_003147.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 50/250 reads (20%) | called by muse, mutect2, varscan2
- STARD13 | c.2662C>T p.H888Y (on ENST00000336934 / NM_001243476.3; = p.H770Y on NM_052851.3) | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2
- STAT3 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 36/587 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2
- STK31 | c.1131G>C p.M377I | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- STX11 | c.451A>C p.M151L | Missense Mutation (SNP) | VAF 98/448 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNDIG1 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TARBP1 | c.4231C>G p.Q1411E | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TBC1D9B | c.3118G>A p.E1040K (on ENST00000356834 / NM_198868.3; = p.E1023K on NM_015043.4) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- TGFBR3L | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TGOLN2 | c.1010C>G p.S337* | Nonsense Mutation (SNP) | VAF 18/518 reads (3%) | called by muse, mutect2
- TICRR | c.5215G>C p.E1739Q | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TLK1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TMCO5A | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TMEM132C | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- TMEM179B | c.498+3G>A | Splice Region (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TMEM216 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMTC4 | c.2060G>T p.S687I (on ENST00000376234 / NM_001350577.2; = p.S706I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TNXB | c.11642G>A p.G3881E (on ENST00000647633; = p.G3634E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/1262 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV7 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- TRBV28 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM51GP | c.1141G>T p.G381* | Nonsense Mutation (SNP) | VAF 60/469 reads (13%) | called by muse, mutect2, varscan2
- TRIP12 | c.5578G>A p.E1860K | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- TRIR | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.058); called by muse, mutect2
- TRIR | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRPA1 | c.3086T>A p.I1029K | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRPA1 | c.3035C>A p.S1012Y | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.35475C>A p.F11825L (on ENST00000591111; = p.F10898L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.6199G>C p.D2067H (on ENST00000591111; = p.D2021H on NM_003319.4) | Missense Mutation (SNP) | VAF 38/452 reads (8%) | PolyPhen benign (0.344); called by muse, mutect2
- TUB | c.203+1G>T p.X68_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- TUBB8 | c.277+1G>T p.X93_splice | Splice Site (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- TXNRD2 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- UBR1 | c.3538C>T p.Q1180* | Nonsense Mutation (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- UGT1A3 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- UGT2B15 | c.557G>C p.G186A | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); called by muse, mutect2
- UHRF1BP1L | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- UNC13A | c.3862G>C p.E1288Q | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2
- UNC79 | c.6956A>T p.E2319V (on ENST00000393151 / NM_001346218.2; = p.E2142V on NM_020818.5) | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- VCAN | c.4802T>A p.V1601D | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, varscan2
- VWCE | c.2467_2468insAA p.P823Qfs*9 | Frame Shift Ins (INS) | VAF 43/253 reads (17%) | called by mutect2, pindel, varscan2
- WDR24 | c.1729C>G p.Q577E (on ENST00000248142; = p.Q447E on NM_032259.4) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.152); called by muse, mutect2
- WNK3 | c.3771T>A p.C1257* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- XIRP2 | c.7750G>A p.E2584K (on ENST00000628543; = p.E2759K on NM_152381.6) | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- XKR6 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- YTHDF1 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZADH2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ZC3H6 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 17/438 reads (4%) | called by muse, mutect2
- ZEB1 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ZNF133 | c.1444A>G p.I482V (on ENST00000316358 / NM_001352454.2; = p.I481V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF256 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- ZNF256 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- ZNF256 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ZNF521 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.08); called by muse, mutect2
- ZNF621 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.842); called by muse, mutect2
- ZNF730 | c.657T>A p.H219Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ZNF8 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZNF839 | c.883G>A p.E295K (on ENST00000558850 / NM_001267827.1; = p.E411K on NM_018335.5) | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ABCB11 | c.2877C>T p.F959= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- ABCC11 | c.2127A>G p.K709= | Silent (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
- ABCF2 | c.384C>G p.L128= | Silent (SNP) | VAF 23/408 reads (6%) | called by muse, mutect2
- ACOX3 | c.1107C>T p.F369= | Silent (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- ADGRB1 | c.3168G>A p.L1056= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- ALLC | c.12A>C p.A4= | Silent (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.930C>G p.L310= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- ARPP21 | c.1239C>A p.S413= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- ASNS | c.426C>G p.V142= | Silent (SNP) | VAF 28/308 reads (9%) | catalogued as COSV51551593; called by muse, mutect2
- ASPM | c.6501G>A p.L2167= | Silent (SNP) | VAF 40/537 reads (7%) | catalogued as COSV54131586; called by muse, mutect2
- ATM | c.6219C>G p.L2073= | Silent (SNP) | VAF 25/352 reads (7%) | catalogued as rs752478345; ClinVar: likely benign; called by muse, mutect2
- C21orf91 | c.699G>C p.L233= | Silent (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- CCDC8 | c.618G>A p.L206= | Silent (SNP) | VAF 28/435 reads (6%) | catalogued as rs746565870; called by muse, mutect2
- CDH10 | c.2211C>A p.A737= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as COSV100053203; called by muse, mutect2, varscan2
- CDH12 | c.810C>A p.P270= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV101201497, COSV66438116; called by muse, mutect2
- CDK12 | c.2013C>G p.L671= | Silent (SNP) | VAF 9/225 reads (4%) | called by muse, mutect2
- CHRNA6 | c.171C>T p.D57= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV52381330; called by muse, mutect2, varscan2
- CHRNG | c.438C>T p.F146= | Silent (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- CILP2 | c.1029C>T p.H343= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as rs145392584; called by muse, mutect2, varscan2
- CLCA2 | c.1170C>T p.I390= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- CLRN1 | c.381T>A p.P127= (on ENST00000327047 / NM_174878.3; = p.P51= on NM_052995.2) | Silent (SNP) | VAF 71/415 reads (17%) | called by muse, mutect2, varscan2
- COLEC11 | c.15G>T p.L5= | Silent (SNP) | VAF 31/293 reads (11%) | called by muse, mutect2, varscan2
- CPEB2 | c.12C>T p.F4= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV52595781; called by muse, mutect2
- CTNND2 | c.3567G>A p.L1189= | Silent (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- CYBB | c.915C>T p.F305= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as CD044781; called by muse, mutect2
- DAPK3 | c.282G>A p.E94= | Silent (SNP) | VAF 20/265 reads (8%) | called by muse, mutect2
- DCSTAMP | c.849C>T p.F283= | Silent (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- DDX39A | c.102C>T p.I34= | Silent (SNP) | VAF 25/373 reads (7%) | called by muse, mutect2
- DLG1 | c.1560C>G p.L520= | Silent (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- DNAH2 | c.10206G>A p.L3402= | Silent (SNP) | VAF 9/246 reads (4%) | catalogued as COSV66719027; called by muse, mutect2
- DNER | c.1380C>T p.F460= | Silent (SNP) | VAF 21/351 reads (6%) | called by muse, mutect2
- EPG5 | c.3297C>T p.V1099= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- EXOSC10 | c.2652G>A p.Q884= (on ENST00000376936 / NM_001001998.3; = p.Q859= on NM_002685.4) | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- FA2H | c.153G>T p.R51= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- FAM171A1 | c.2499G>A p.E833= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- FAM50A | c.21C>T p.A7= | Silent (SNP) | VAF 8/83 reads (10%) | called by muse, varscan2
- FBXL16 | c.306C>T p.L102= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs893498250, COSV100178724; called by muse, mutect2
- GEMIN4 | c.348C>G p.L116= | Silent (SNP) | VAF 18/193 reads (9%) | catalogued as rs778223944; called by muse, mutect2
- GRIK2 | c.1791T>G p.P597= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- GTF2F2 | c.42G>A p.Q14= | Silent (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- H2AZ2 | c.354G>C p.L118= | Silent (SNP) | VAF 15/199 reads (8%) | called by muse, mutect2
- HAS2 | c.510C>T p.H170= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as rs373683528; called by muse, mutect2
- HDAC11 | c.249C>G p.L83= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- HIF3A | c.1506C>T p.L502= (on ENST00000377670 / NM_152795.4; = p.L433= on NM_022462.4) | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99356112; called by muse, mutect2
- HMCN1 | c.4977G>A p.L1659= | Silent (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- HPSE2 | c.309C>A p.T103= | Silent (SNP) | VAF 23/304 reads (8%) | called by muse, mutect2
- HSD11B1 | c.729G>T p.L243= | Silent (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- HYOU1 | c.66C>G p.L22= | Silent (SNP) | VAF 28/342 reads (8%) | catalogued as rs1213327386; called by muse, mutect2
- IDUA | c.816C>A p.I272= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- IGLV2-14 | c.162C>G p.V54= | Silent (SNP) | VAF 25/377 reads (7%) | called by muse, mutect2
- IL1RL1 | c.1075C>T p.L359= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV99294645; called by muse, mutect2
- ISM2 | c.1173C>T p.R391= (on ENST00000342219 / NM_199296.3; = p.A276V on NM_182509.4) | Silent (SNP) | VAF 14/181 reads (8%) | catalogued as rs1192446145, COSV53635308; called by muse, mutect2
- ITGAX | c.1386C>G p.L462= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- KCNK15 | c.774C>A p.A258= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- LGALS9 | c.694C>T p.L232= (on ENST00000395473 / NM_009587.3; = p.L200= on NM_002308.4) | Silent (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- LRRC32 | c.1095G>T p.L365= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as rs1350562900; called by muse, mutect2
- LTF | c.2079G>C p.L693= | Silent (SNP) | VAF 21/333 reads (6%) | catalogued as COSV99212241; called by muse, mutect2
- MAGEB3 | c.1041G>A p.*347= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, varscan2
- MOGAT3 | c.957G>T p.L319= | Silent (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- MSLNL | c.1743C>G p.L581= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1240318104; called by muse, mutect2
- MUC16 | c.35016C>T p.F11672= | Silent (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2, varscan2
- MUC17 | c.1452C>A p.T484= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as COSV100074936; called by muse, mutect2, varscan2
- MYH2 | c.792T>A p.A264= | Silent (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- MYO18B | c.2373C>A p.S791= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV59125139; called by muse, mutect2
- MYOM2 | c.3636C>T p.I1212= | Silent (SNP) | VAF 11/214 reads (5%) | catalogued as rs746197064; called by muse, mutect2
- NDN | c.45C>A p.A15= | Silent (SNP) | VAF 7/44 reads (16%) | called by mutect2, varscan2
- NDUFB4 | c.300C>T p.F100= | Silent (SNP) | VAF 18/287 reads (6%) | catalogued as COSV99481965; called by muse, mutect2
- NINL | c.3078C>G p.L1026= | Silent (SNP) | VAF 11/209 reads (5%) | catalogued as COSV54008769; called by muse, mutect2
- NLRP2 | c.918G>A p.G306= | Silent (SNP) | VAF 37/207 reads (18%) | catalogued as COSV54755472; called by muse, mutect2, varscan2
- NOS3 | c.186C>T p.P62= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1048775049, COSV52487780; called by muse, mutect2, varscan2
- NYAP1 | c.2472C>A p.S824= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.19248G>A p.L6416= | Silent (SNP) | VAF 29/286 reads (10%) | catalogued as rs1341092125; called by muse, mutect2
- OR2F1 | c.720G>T p.T240= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as rs369493419, COSV67331608; called by muse, varscan2
- OR4C15 | c.432C>A p.T144= (on ENST00000314644; = p.T90= on NM_001001920.2) | Silent (SNP) | VAF 32/312 reads (10%) | catalogued as rs1433780878; called by muse, mutect2, varscan2
- PADI4 | c.237G>T p.T79= | Silent (SNP) | VAF 33/334 reads (10%) | catalogued as rs750711340, COSV64922926; called by muse, mutect2, varscan2
- PAX4 | c.555G>T p.L185= | Silent (SNP) | VAF 35/292 reads (12%) | called by mutect2, varscan2
- PCDH7 | c.138C>A p.V46= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- PGBD1 | c.1575C>G p.L525= | Silent (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- PHOX2B | c.420G>A p.A140= | Silent (SNP) | VAF 24/331 reads (7%) | called by muse, mutect2
- PKN3 | c.1156C>T p.L386= | Silent (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- PLXNA4 | c.4176C>G p.T1392= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- PROM2 | c.1812G>T p.R604= | Silent (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- PRRT3 | c.2268C>T p.R756= | Silent (SNP) | VAF 54/287 reads (19%) | called by muse, mutect2, varscan2
- PSMB7 | c.621C>T p.F207= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as COSV52332368; called by muse, mutect2
- PTGES2 | c.501C>T p.V167= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV52968456; called by muse, mutect2
- PTGFRN | c.2478G>A p.L826= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- RAPSN | c.111G>A p.S37= | Silent (SNP) | VAF 28/319 reads (9%) | catalogued as rs146825957; ClinVar: likely benign; called by muse, mutect2
- RBM6 | c.1854A>G p.Q618= | Silent (SNP) | VAF 44/396 reads (11%) | catalogued as rs770294083; called by muse, mutect2, varscan2
- REG3A | c.468G>A p.L156= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- RFX8 | c.198G>A p.L66= | Silent (SNP) | VAF 7/175 reads (4%) | catalogued as COSV65179658; called by muse, mutect2
- RIPK1 | c.246C>T p.I82= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as rs1485569653; called by muse, mutect2
- RPRD1B | c.438G>C p.L146= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- RUNDC3A | c.246G>A p.V82= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- SEMA6A | c.204C>T p.L68= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- SETD1A | c.330G>A p.L110= | Silent (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- SHC1 | c.948C>G p.L316= (on ENST00000368445 / NM_183001.5; = p.L206= on NM_003029.5) | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV63534657; called by muse, mutect2, varscan2
- SLC13A1 | c.318G>A p.K106= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- SLC27A2 | c.144G>A p.K48= | Silent (SNP) | VAF 28/279 reads (10%) | called by muse, mutect2
- SLC5A5 | c.177G>A p.V59= | Silent (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- SLC6A17 | c.1470G>A p.K490= | Silent (SNP) | VAF 41/424 reads (10%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1557C>T p.G519= | Silent (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- SMC2 | c.360C>T p.V120= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- SPATA31A1 | c.573T>C p.L191= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs1379963068; called by mutect2, varscan2
- SPTA1 | c.699C>A p.P233= | Silent (SNP) | VAF 65/552 reads (12%) | catalogued as COSV63751052; called by muse, mutect2, varscan2
- SSTR2 | c.84C>T p.T28= | Silent (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- STRA8 | c.48C>T p.I16= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- TDRD9 | c.1494A>G p.G498= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs1028920764, COSV59149278; called by muse, mutect2
- TEDDM1 | c.495G>T p.L165= | Silent (SNP) | VAF 38/408 reads (9%) | catalogued as rs776969762; called by muse, mutect2
- TLR10 | c.1272C>T p.V424= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- TMC4 | c.1467C>G p.L489= (on ENST00000617472 / NM_001145303.3; = p.L483= on NM_144686.4) | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as COSV55829161; called by muse, mutect2
- TMEM8B | c.1104C>T p.R368= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- TOMM70 | c.159G>T p.A53= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- TRAK2 | c.2490G>A p.L830= | Silent (SNP) | VAF 24/470 reads (5%) | catalogued as COSV60271157; called by muse, mutect2
- TTN | c.42570C>T p.F14190= (on ENST00000591111; = p.F6766= on NM_003319.4) | Silent (SNP) | VAF 16/542 reads (3%) | catalogued as COSV60305589; called by muse, mutect2
- UGT3A2 | c.726G>A p.L242= | Silent (SNP) | VAF 15/336 reads (4%) | called by muse, mutect2
- USP34 | c.2904G>C p.V968= | Silent (SNP) | VAF 8/220 reads (4%) | called by muse, mutect2
- VASP | c.1068G>A p.K356= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- VGF | c.1009C>T p.L337= | Silent (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- ZFAT | c.3105C>T p.L1035= | Silent (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- ZNF521 | c.2994G>A p.Q998= | Silent (SNP) | VAF 16/247 reads (6%) | called by muse, mutect2
- ZNF565 | c.918G>T p.L306= (on ENST00000355114; = p.L266= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- ZNF735 | c.969A>G p.K323= | Silent (SNP) | VAF 17/282 reads (6%) | called by muse, mutect2
- AATK | c.*14C>G | 3'UTR (SNP) | VAF 21/161 reads (13%) | catalogued as COSV100353033, COSV100353088; called by muse, mutect2, varscan2
- AC006372.4 | n.131C>T | RNA (SNP) | VAF 8/128 reads (6%) | catalogued as rs1034200628; called by muse, mutect2
- AC022415.2 | c.*3369G>C | 3'UTR (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2653+129_2653+136del | Intron (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel
- ALG12 | c.-11G>A | 5'UTR (SNP) | VAF 23/362 reads (6%) | called by muse, mutect2
- AP000769.3 | chr11:65501257 T>G | 5'Flank (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- ARPP21 | c.898-18C>A | Intron (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.2472+38G>T | Intron (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- BCL2L2 | c.*2140G>A | 3'UTR (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- BCOR | chrX:40049924 C>G | 3'Flank (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- C11orf52 | chr11:111929909 C>T | 3'Flank (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- C16orf91 | c.-10C>G | 5'UTR (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- C4A | chr6:32006317 C>T | 3'Flank (SNP) | VAF 23/641 reads (4%) | catalogued as rs532258592; called by muse, mutect2
- CALU | c.415+188A>G | Intron (SNP) | VAF 36/243 reads (15%) | catalogued as rs1469371528, COSV50821174; called by muse, mutect2, varscan2
- CASP10 | c.347+36C>G | Intron (SNP) | VAF 45/273 reads (16%) | catalogued as rs747046527; called by muse, mutect2, varscan2
- CCNYL3 | n.892C>A | RNA (SNP) | VAF 32/208 reads (15%) | catalogued as rs984730371; called by muse, mutect2, varscan2
- CDIPT | c.43+22G>T | Intron (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- CDKN3 | c.552+329G>T | Intron (SNP) | VAF 16/251 reads (6%) | called by muse, mutect2
- CHRNA7 | c.990+20G>T | Intron (SNP) | VAF 18/64 reads (28%) | catalogued as COSV60967865; called by muse, mutect2, varscan2
- CKS1B | c.59+106G>A | Intron (SNP) | VAF 35/506 reads (7%) | catalogued as rs937451790, COSV58316909; called by muse, mutect2
- CREB3L4 | c.421+37C>T | Intron (SNP) | VAF 42/271 reads (15%) | catalogued as rs953766192; called by muse, mutect2, varscan2
- CSGALNACT1 | c.*882G>A | 3'UTR (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- DCXR | c.53-21C>T | Intron (SNP) | VAF 17/354 reads (5%) | called by muse, mutect2
- DDX11 | c.2372+34G>A | Intron (SNP) | VAF 18/341 reads (5%) | catalogued as rs1267515337; called by muse, mutect2
- EIF4E2 | chr2:232574075 G>A | 3'Flank (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- EP400P1 | n.773T>A | RNA (SNP) | VAF 39/300 reads (13%) | called by muse, mutect2, varscan2
- FAM21FP | n.217A>T | RNA (SNP) | VAF 55/332 reads (17%) | called by muse, mutect2, varscan2
- FBXW9 | chr19:12689164 G>A | 3'Flank (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- FUS | c.-20C>G | 5'UTR (SNP) | VAF 69/483 reads (14%) | catalogued as rs1439152844; called by muse, mutect2, varscan2
- GCH1 | c.*16+131G>A | Intron (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- GLRXP3 | n.294G>T | RNA (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- GNAO1 | c.723+4039G>T | Intron (SNP) | VAF 18/206 reads (9%) | catalogued as COSV52612824, COSV52619519; called by muse, mutect2
- GPHN | c.-728C>T | 5'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- HCN1 | c.-20G>T | 5'UTR (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- HSP90B3P | n.1012G>C | RNA (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- ICMT | c.284+426G>A | Intron (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- INTS1 | c.*15A>G | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- KDM5A | c.4074+39C>T | Intron (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- LINC01098 | n.551C>G | RNA (SNP) | VAF 11/72 reads (15%) | catalogued as rs906070824; called by muse, mutect2, varscan2
- LINC02054 | n.2595-11571C>T | Intron (SNP) | VAF 19/237 reads (8%) | catalogued as rs995945313; called by muse, mutect2
- LMO2 | c.-153G>A | 5'UTR (SNP) | VAF 5/96 reads (5%) | catalogued as COSV57646826; called by muse, mutect2
- LUC7L | c.61+16C>A | Intron (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- MAX | c.172-6233C>T | Intron (SNP) | VAF 30/474 reads (6%) | called by muse, mutect2
- MCRIP1 | c.-48-1257G>C | Intron (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- MPRIP | c.123+14724C>G | Intron (SNP) | VAF 11/295 reads (4%) | called by muse, mutect2
- MRPS36P1 | chr3:6770062 G>T | 3'Flank (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-149C>T | 5'UTR (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- NACA | c.70+3467C>T | Intron (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- NBPF22P | n.1191G>A | RNA (SNP) | VAF 76/464 reads (16%) | called by muse, mutect2, varscan2
- NR1D1 | c.-14C>T | 5'UTR (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- NXPH3 | c.*2394C>T | 3'UTR (SNP) | VAF 13/381 reads (3%) | called by muse, mutect2
- PA2G4 | c.-175C>T | 5'UTR (SNP) | VAF 62/310 reads (20%) | called by muse, mutect2, varscan2
- PADI1 | c.*124C>A | 3'UTR (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- PALLD | c.*194G>A | 3'UTR (SNP) | VAF 13/187 reads (7%) | called by muse, mutect2
- PDLIM3 | c.293-51G>T | Intron (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2, varscan2
- PIP5K1A | c.*12C>T | 3'UTR (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- PLEKHG4 | c.*5G>T | 3'UTR (SNP) | VAF 67/364 reads (18%) | catalogued as COSV100431156; called by muse, mutect2, varscan2
- PRAC1 | c.-12G>A | 5'UTR (SNP) | VAF 8/208 reads (4%) | called by muse, mutect2
- PRSS40A | n.142-2203G>T | Intron (SNP) | VAF 49/622 reads (8%) | called by muse, mutect2
- PRSS40A | n.317+47C>A | Intron (SNP) | VAF 32/357 reads (9%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.-86G>C | 5'UTR (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- RACK1 | chr5:181247164 C>T | 5'Flank (SNP) | VAF 8/79 reads (10%) | catalogued as rs1036950453; called by mutect2, varscan2
- RAI1 | c.-16-14091G>A | Intron (SNP) | VAF 14/341 reads (4%) | catalogued as rs1053935589; called by muse, mutect2
- RALGDS | c.1758+12G>T | Intron (SNP) | VAF 34/395 reads (9%) | called by muse, mutect2
- RBM44 | c.-98-1719G>A | Intron (SNP) | VAF 9/172 reads (5%) | catalogued as rs1214433811, COSV100390098; called by muse, mutect2
- RGS1 | c.444+33C>A | Intron (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- SCGB2A2 | c.-1C>T | 5'UTR (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- SCML2P1 | n.505+57G>C | Intron (SNP) | VAF 8/142 reads (6%) | catalogued as rs965886825; called by muse, mutect2
- SHISA8 | chr22:41909926 G>A | 3'Flank (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- SNAI2 | c.-37T>G | 5'UTR (SNP) | VAF 20/300 reads (7%) | catalogued as COSV99194916; called by muse, mutect2
- SPATA31C1 | n.855G>T | RNA (SNP) | VAF 39/661 reads (6%) | called by muse, mutect2
- SSX6P | n.331G>A | RNA (SNP) | VAF 16/109 reads (15%) | catalogued as rs142081329; called by muse, mutect2, varscan2
- TLX1NB | n.1353G>C | RNA (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TMEM39A | c.420+1169C>G | Intron (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
- TSPAN12 | c.-17C>T | 5'UTR (SNP) | VAF 36/464 reads (8%) | catalogued as rs765576093; called by muse, mutect2
- USE1 | c.394+248G>C | Intron (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- VPS11 | c.-125T>A | 5'UTR (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75511108 G>A | 3'Flank (SNP) | VAF 27/556 reads (5%) | catalogued as rs782642818; called by muse, mutect2
- ZFAT | c.2888-181C>T | Intron (SNP) | VAF 10/101 reads (10%) | catalogued as rs1391375251; called by muse, mutect2, varscan2
